Gene-level copy-number profile of tumor specimen TCGA-IN-A6RN-01A from TCGA case TCGA-IN-A6RN, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,409 days).
Specimen TCGA-IN-A6RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.36f83a3a-5071-4024-b2b6-f908171e7b22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/482b1cc8-7fec-4caf-8792-fd5cf61a6cf3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 7,949; copy number 2: 44,004; copy number 3: 5,779; copy number 4: 1,542; copy number 5: 147; copy number 6: 66; copy number 7: 86; copy number 8: 56; copy number 12: 83; copy number 13: 35; copy number 14: 50; copy number 16: 6; copy number 23: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RN-01A-12D-A33S-01): tumor purity 0.6, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,700,142, 3 genes: AC093840.1, AC093840.2, AC084741.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 539 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,540,768–169,630,193, 25 genes, copy number 5 (within-gene range 2–5): XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP.
- chr2:105,744,912–106,078,155, 4 genes, copy number 5: NCK2, AC010978.1, AC009505.1, ECRG4.
- chr3:184,499,484–185,980,872, 28 genes, copy number 6: AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P.
- chr3:193,578,812–194,086,826, 14 genes, copy number 6 (within-gene range 3–6): AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2.
- chr5:39,092,658–39,274,528, 3 genes, copy number 5 (within-gene range 2–5): AC008964.1, FYB1, GOLGA5P1.
- chr6:41,494,853–42,050,357, 24 genes, copy number 6 (within-gene range 4–6): FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1.
- chr6:42,963,865–44,095,585, 57 genes, copy number 5 (within-gene range 4–5): PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 2–5): PCAT1.
- chr8:126,671,522–127,742,951, 14 genes, copy number 5: RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 5: MIR1204, AC084123.1.
- chr10:71,711,701–73,358,859, 55 genes, copy number 8 (within-gene range 4–8): C10orf105, VSIR, MIR7152, PSAP, RNU7-38P, AC073370.1, CHST3, AC022392.1, SPOCK2, ASCC1, AL607035.1, RPL15P14, ANAPC16, Y_RNA, DDIT4, DDIT4-AS1, DNAJB12, MICU1, RNU6-805P, AC091769.1, SNX19P4, AL513185.1, AL513185.2, RN7SL840P, HMGN2P34, AL513185.3, Y_RNA, MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1, OIT3, NPM1P24, PLA2G12B, RPL17P50, P4HA1, AL731563.1, AL731563.2, Y_RNA, AL731563.3, NUDT13, AC016394.1, SNORA11F, ECD, FAM149B1, DNAJC9, Y_RNA, EIF4A2P2, AC016394.2, DNAJC9-AS1, MRPS16, DNAJC9-AS1, CFAP70, RNU6-833P.
- chr12:27,798,641–32,383,633, 99 genes, copy number 12–23 (within-gene range 1–23) (broad region; genes not listed).
- chr12:68,473,741–70,354,993, 50 genes, copy number 14: AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1.
- chr12:70,443,784–72,728,844, 33 genes, copy number 7: RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:86,015,697–86,016,441, 1 gene, copy number 8: AC139697.1.
- chr14:37,827,798–38,371,338, 8 genes, copy number 5 (within-gene range 2–5): RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr15:90,001,324–90,082,206, 1 gene, copy number 13 (within-gene range 4–13): ZNF710.
- chr15:90,074,512–90,717,141, 34 genes, copy number 13 (within-gene range 3–13): ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585.
- chr18:11,326,270–11,552,847, 7 genes, copy number 5: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1.
- chr18:52,340,197–53,535,903, 1 gene, copy number 5 (within-gene range 2–5): DCC.
- chr18:53,237,101–55,146,645, 25 genes, copy number 5: MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.
- chr18:76,794,732–79,612,303, 53 genes, copy number 7: ZNF236-DT, RNU6-346P, AC027575.2, ZNF236, RPL26P35, Metazoa_SRP, AC027575.1, AC093330.1, MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4.

Autosomal genes at a single copy (total copy number 1): 7,949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
